Gene-level copy-number profile of tumor specimen TCGA-KK-A6E0-01A from TCGA case TCGA-KK-A6E0, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.4 years (21,700 days).
Specimen TCGA-KK-A6E0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.af915427-c598-40e8-86b8-a5087214b30c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A6E0-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f9c3b78d-9401-4131-916e-fa9fe4727a58

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 108; copy number 1: 11,247; copy number 2: 48,388; copy number 3: 76.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A6E0-01A-11D-A30W-01): tumor purity 0.64, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:99,698,242–99,791,753, 4 genes: HMGB3P10, FRRS1, RNU4-75P, Y_RNA.
- chr1:165,827,614–166,481,565, 14 genes (within-gene range 0–1): UCK2, AL358115.1, MIR3658, AL606495.1, RPS3AP10, RNA5SP64, FAM78B, FAM78B-AS1, AL596087.3, MIR921, AL596087.2, AL596087.1, AL583804.1, FMO7P.
- chr1:177,928,788–178,093,984, 4 genes (within-gene range 0–1): CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1.
- chr4:135,045,464–135,315,522, 4 genes: AC104619.3, AC107463.1, LINC02485, U6.
- chr5:18,547,312–18,547,605, 1 gene: RN7SL58P.
- chr5:18,958,147–18,958,413, 1 gene: Metazoa_SRP.
- chr5:21,750,673–24,353,443, 22 genes (within-gene range 0–1): CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1.
- chr5:25,087,450–26,484,711, 15 genes: LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2.
- chr5:98,025,965–98,995,013, 20 genes: AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1.
- chr8:51,319,577–52,022,974, 9 genes (within-gene range 0–1): PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2.
- chr10:37,297,398–37,303,109, 2 genes: RN7SL314P, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,872. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
